Somatic mutation profile of tumor specimen TARGET-10-PATHWV-09A (aliquot TARGET-10-PATHWV-09A-01D) from TARGET case TARGET-10-PATHWV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.6 years (3,127 days).
Specimen TARGET-10-PATHWV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a2557e2-3d59-41bf-9ec1-e21b8d9a951c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATHWV-10A (Blood Derived Normal), aliquot TARGET-10-PATHWV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66514436-ff56-4dfa-90e3-d7f32d3ebbc0

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 2, 3'UTR 1, 5'Flank 1, In Frame Ins 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASH1L | c.4922T>G p.L1641R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64211647; called by muse, mutect2
- HK1 | c.2717C>A p.A906D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100067498; called by muse, mutect2
- L3MBTL4 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757230528, COSV53115908; called by muse, mutect2, varscan2
- MMRN2 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV64401145; called by muse, mutect2, varscan2
- MTA3 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68136004; called by muse, mutect2, varscan2
- OR11H6 | c.841A>C p.T281P | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV59644756, COSV59645289; called by muse, mutect2, varscan2
- PCDHB8 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as rs782098169, COSV50808953; called by muse, mutect2
- PHF6 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 30/30 reads (100%) | catalogued as COSV59699190; called by muse, mutect2, varscan2
- SATB1 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58667618; called by muse, mutect2, varscan2
- TMEM132B | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774667643, COSV54746669; called by muse, mutect2, varscan2
- FAM149A | c.973C>A p.Q325K (on ENST00000356371 / NM_001367768.2; = p.Q34K on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GCNA | c.310+2C>A p.X104_splice | Splice Site (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- IGHD6-19 | c.19_20insCTCACC p.Y7delinsSHH | In Frame Ins (INS) | VAF 40/104 reads (38%) | called by mutect2, varscan2*
- USP7 | c.1450G>T p.V484L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- ZSCAN23 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2
- COL4A1 | c.1419C>T p.D473= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as rs140440365, COSV65422031, COSV65423996; called by muse, mutect2, varscan2
- IZUMO2 | c.531G>A p.Q177= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2
- ROR2 | c.435C>T p.T145= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as rs779139938, COSV100996074, COSV65221556; called by muse, mutect2, varscan2
- TBC1D2B | c.2430G>T p.L810= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- ZMAT4 | c.618C>A p.S206= | Silent (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505053 T>C | 5'Flank (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- CCDC88B | c.*326G>T | 3'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- DNA2 | c.75-445G>A | Intron (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- DNA2 | c.75-446C>G | Intron (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
